CCDI case PBCLJT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/300bad73-2924-4ac9-837c-d52826765188

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 5.6 years (2,043 days).

Biospecimens (3 samples)
- Sample 0DUHGG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Samples 0DUHH6, 0DUHI9 (2 with the same recorded description): Tissue type: Tumor; Specimen type: Solid Tissue.
